Somatic mutation profile of tumor specimen ALCH-B1RE-TTP1-B (aliquot ALCH-B1RE-TTP1-B-1-0-D-A81V-36) from ALCHEMIST case ALCH-B1RE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 83.6 years (30,553 days).
Specimen ALCH-B1RE-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99a6c294-ae15-47aa-ab0d-664f03c754b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1RE-NB1-A (Blood Derived Normal), aliquot ALCH-B1RE-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49dee59b-e469-424a-ad5c-cecf23a6a950

The open-access MAF lists 49 somatic variants for this specimen: 28 protein-altering or splice-affecting, 13 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 13, Intron 5, Nonsense Mutation 3, 5'UTR 3, Splice Site 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 228/1037 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- CUTA | c.413+1G>T p.X138_splice (on ENST00000488034 / NM_001014840.2; = p.X115_splice on NM_015921.3) | Splice Site (SNP) | VAF 21/433 reads (5%) | catalogued as rs113648187; called by muse, mutect2
- CYP4F2 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs570092372, COSV50000769, COSV50003038; called by muse, mutect2, varscan2
- DISC1 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 42/492 reads (9%) | SIFT tolerated (0.95); PolyPhen benign (0.005); catalogued as rs367543086, COSV54419467; ClinVar: not provided; called by muse, mutect2
- ITSN1 | c.5107G>A p.E1703K | Missense Mutation (SNP) | VAF 14/458 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV67157190; called by muse, mutect2
- LCT | c.5363G>A p.G1788E | Missense Mutation (SNP) | VAF 164/783 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1345936891; called by muse, mutect2, varscan2
- SLC29A2 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 54/854 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100237099; called by muse, mutect2
- SLC8A1 | c.2341C>A p.L781M | Missense Mutation (SNP) | VAF 130/518 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60481511; called by muse, mutect2, varscan2
- SNRPA | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 55/308 reads (18%) | catalogued as COSV54682524; called by muse, mutect2, varscan2
- SRGAP1 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 90/479 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs138338037, COSV100755168; called by muse, mutect2, varscan2
- TSPAN18 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1486297163, COSV100419018; called by muse, mutect2
- VWC2L | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 48/1047 reads (5%) | catalogued as rs1473508513; called by muse, mutect2
- ZNF264 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 21/477 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs1222586960; called by muse, mutect2
- C2orf42 | c.197T>A p.I66N | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2
- CNKSR2 | c.307del p.I103* | Frame Shift Del (DEL) | VAF 62/410 reads (15%) | called by mutect2, pindel, varscan2
- DST | c.255dup p.G86Rfs*16 | Frame Shift Ins (INS) | VAF 59/507 reads (12%) | called by mutect2, pindel, varscan2
- DVL1 | c.332G>A p.G111D | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.539); called by muse, mutect2
- GBP2 | c.1006C>A p.Q336K | Missense Mutation (SNP) | VAF 38/1498 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.227); called by muse, mutect2
- IGHA2 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 16/556 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NAV3 | c.1436G>A p.C479Y | Missense Mutation (SNP) | VAF 53/367 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- OR6B2 | c.799T>C p.S267P | Missense Mutation (SNP) | VAF 16/554 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.177); called by muse, mutect2
- PLS3 | c.582+1G>A p.X194_splice | Splice Site (SNP) | VAF 9/233 reads (4%) | called by muse, mutect2
- PRKAR1B | c.505A>G p.N169D | Missense Mutation (SNP) | VAF 23/352 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PROSER1 | c.1409C>G p.S470C | Missense Mutation (SNP) | VAF 18/482 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- PTPRR | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 74/627 reads (12%) | called by muse, mutect2, varscan2
- SRPRA | c.1295C>G p.S432C | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAPPC8 | c.128T>G p.L43R | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- TRPV6 | c.1847C>T p.A616V | Missense Mutation (SNP) | VAF 106/578 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACAP1 | c.1065G>A p.V355= | Silent (SNP) | VAF 26/342 reads (8%) | catalogued as COSV50138108; called by muse, mutect2
- DPP6 | c.1395G>C p.V465= (on ENST00000377770 / NM_001364500.2; = p.V403= on NM_001936.5) | Silent (SNP) | VAF 12/212 reads (6%) | called by muse, mutect2
- GRHL2 | c.1149G>T p.G383= | Silent (SNP) | VAF 42/1174 reads (4%) | called by muse, mutect2
- JADE3 | c.330G>A p.R110= | Silent (SNP) | VAF 23/418 reads (6%) | called by muse, mutect2
- LMCD1 | c.843G>A p.P281= | Silent (SNP) | VAF 74/968 reads (8%) | catalogued as rs1421745447; called by muse, mutect2
- PBXIP1 | c.2109G>A p.G703= | Silent (SNP) | VAF 14/300 reads (5%) | called by muse, mutect2
- PIR | c.51G>A p.S17= | Silent (SNP) | VAF 109/674 reads (16%) | catalogued as rs146277049; called by muse, mutect2, varscan2
- SGSM1 | c.1440G>A p.P480= | Silent (SNP) | VAF 40/162 reads (25%) | catalogued as rs371170667; called by muse, mutect2, varscan2
- SPRY1 | c.861T>C p.Y287= | Silent (SNP) | VAF 116/721 reads (16%) | catalogued as rs370375351; called by muse, mutect2, varscan2
- TDP1 | c.945G>A p.S315= | Silent (SNP) | VAF 24/492 reads (5%) | catalogued as rs1231168955, COSV59642505; called by muse, mutect2
- TGM1 | c.567C>T p.G189= | Silent (SNP) | VAF 33/406 reads (8%) | called by muse, mutect2
- TNFRSF18 | c.483G>A p.E161= | Silent (SNP) | VAF 36/575 reads (6%) | catalogued as rs1030313148; called by muse, mutect2
- ZNF408 | c.1782G>A p.L594= | Silent (SNP) | VAF 19/414 reads (5%) | called by muse, mutect2
- ASB6 | c.-2C>T | 5'UTR (SNP) | VAF 15/116 reads (13%) | called by muse, mutect2, varscan2
- CNGB3 | c.-46G>T | 5'UTR (SNP) | VAF 48/570 reads (8%) | called by muse, mutect2
- FXYD3 | c.-47C>G | 5'UTR (SNP) | VAF 20/709 reads (3%) | called by muse, mutect2
- HACD1 | c.257+1344C>T | Intron (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- MUCL1 | c.100+21C>A | Intron (SNP) | VAF 13/400 reads (3%) | called by muse, mutect2
- RBM43 | c.3+268C>T | Intron (SNP) | VAF 124/683 reads (18%) | called by muse, mutect2, varscan2
- TCIRG1 | c.1554+9T>A | Intron (SNP) | VAF 22/656 reads (3%) | catalogued as rs1464595916; called by muse, mutect2
- TRAK1 | c.287-16397A>T | Intron (SNP) | VAF 26/442 reads (6%) | called by muse, mutect2
